Somatic mutation profile of tumor specimen 0DNRUR from CCDI case PBBYGB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin of lower limb and hip; Age at diagnosis: 12.6 years (4,608 days).
Specimen 0DNRUR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b14a6567-404f-4eda-9d7e-38a90a87f482.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNRTM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cd168dd-b596-4a71-b905-5fece6e972ab

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NXN | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs1044477260; called by muse, varscan2
- PADI2 | c.-71del | 5'UTR (DEL) | VAF 3/17 reads (18%) | called by mutect2, varscan2
